TARGET case TARGET-40-PAPXWB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/648b49d1-851f-5a36-8905-532fc44d9fd5

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 15.3 years (5,604 days); Year of diagnosis: 2006; Metastasis at diagnosis: No Metastasis; Days to last follow up: 2,777 days (7.6 years).
   Treatment given: Protocol identifier: AOST0331.

Follow-up (2 entries)
- Days to follow up: 2,201 days (6.0 years); Progression or recurrence: Yes; Days to progression: 2,201 days (6.0 years); Days to first event: 2,201 days (6.0 years); First event: Relapse.
- Days to follow up: 2,777 days (7.6 years); Year of follow up: 2014.

Biospecimens (2 samples)
- Sample TARGET-40-PAPXWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PAPXWB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAPXWB-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 99
- % Non Tumor Nuclei: Top from Biopsy: 1
- % Cellular Tumor: Top from Biopsy: 81
- % Normal: Top from Biopsy: 7
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 12
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 72
- % Normal: Bottom from Biopsy: 3
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 25
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2777
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Amputation
- Primary site progression: No
- Site of initial relapse: Non-bone, non-lung
- Histologic response: Stage 3/4 (91-100 % necrosis)
